Somatic mutation profile of tumor specimen TARGET-50-PAJMJT-01A (aliquot TARGET-50-PAJMJT-01A-01D) from TARGET case TARGET-50-PAJMJT, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Alive; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 5.3 years (1,921 days).
Specimen TARGET-50-PAJMJT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4b74af2-26c6-4670-8a8a-5311d2b26648.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJMJT-10A (Blood Derived Normal), aliquot TARGET-50-PAJMJT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bba0ab91-3358-470f-8f07-711d0bf31716

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD9 | c.590G>A p.G197D | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1014032688, COSV50530203; called by muse, mutect2, varscan2
- DNAH5 | c.10766A>G p.Q3589R | Missense Mutation (SNP) | VAF 86/194 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54248925; called by muse, mutect2
- L3MBTL2 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV53434188; called by muse, mutect2
- MIGA1 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 134/244 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs769147848, COSV66223478; called by muse, mutect2, varscan2
- SMC4 | c.2569A>G p.K857E | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); catalogued as rs1299747050, COSV61004484; called by muse, mutect2, varscan2
- AMER1 | c.212_231del p.S71Kfs*24 | Frame Shift Del (DEL) | VAF 11/66 reads (17%) | called by mutect2, pindel, varscan2
- KAT2A | c.2445C>G p.C815W | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.939); called by muse, varscan2
- STAG3 | c.1113C>T p.Y371= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs749436216, COSV57929845; called by muse, mutect2, varscan2
- TIAM1 | c.2259C>T p.N753= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as COSV54548208; called by muse, mutect2, varscan2
- TNS4 | c.306G>T p.L102= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99563983; called by muse, mutect2, varscan2
- MLC1 | c.*11C>A | 3'UTR (SNP) | VAF 10/23 reads (43%) | catalogued as rs369175737; called by muse, varscan2
